Surgical pathology report (de-identified scan), TCGA case TCGA-Z6-A8JE, project TCGA-ESCA (Esophageal Carcinoma), tissue source site Cureline, specimen TCGA-Z6-A8JE-01A (Primary Tumor).

ICD-O-3
Carcinoma, squamous cell NOS 8070/3
Site: ~~CSCF~~ Esophagus, proximal third C15.3
path Esophagus NOS C15.9
5/1/27/14

Case #

Patient: Age (years): Gender: M

Clinical diagnosis: Esophageal cancer

Date of procurement:

Sample:

Gross description: Fragment of esophagus 14.5 cm in length and stomach 3 cm in length with adjacent adipose tissue. Esophageal wall 1 cm from proximal line of resection shows ulcerative tumor 4x5 cm. Section reveals constriction of the esophagus by the tumor by 1.5 cm. Lymphatic nodes in adjacent adipose tissue are soft, 1.5 cm in diameter.

Microscopic description: Poorly differentiated squamous cell carcinoma of the esophagus infiltrating all laminae and adventitia. One of 11 paraesophageal lymphatic nodes shows signs of metastasis. One of 9 paracardial lymphatic nodes shows signs of metastasis.

Final diagnosis: Poorly differentiated squamous cell carcinoma of the esophagus infiltrating all laminae and adventitia

Confidential

MPAA Discrepancy		

Source: NCI Genomic Data Commons file 793cbb0f-e04f-4ddc-b5ad-86af98932dbc (TCGA-Z6-A8JE.EA4E06E4-52C2-442B-AF11-FE969207603A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).